CPTAC case C3L-08314 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/71ba6081-9934-45f3-bb32-54c0426b216c

Demographics
Sex at birth: male; Race: white; Year of birth: 1952; Vital status: Alive; Country of birth: Serbia.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Gastric antrum; Age at diagnosis: 70.1 years (25,593 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: R0; Days to last known disease status: 1,109 days (3.0 years); Progression or recurrence: no; Days to last follow up: 1,109 days (3.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Positive; Lymph nodes positive: 4; Lymph nodes tested: 8.

Follow-up (2 entries)
- Days to follow up: 368 days (1.0 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 1.
- Days to follow up: 751 days (2.1 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 1.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-08314-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 9 days; Initial weight: 468 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-08314-21: Section location: Antrum; Percent tumor nuclei: 65; Percent necrosis: 0.
- Sample C3L-08314-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 12 days; Method of sample procurement: Blood Draw.
